Gene-level copy-number profile of tumor specimen HCM-CSHL-0064-C18-86A from HCMI case HCM-CSHL-0064-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.4 years (27,552 days).
Specimen HCM-CSHL-0064-C18-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 30f47bbe-6576-4b07-8100-de5c1fafb6bb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0064-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/a4720510-170f-4ec6-9e77-10391363bcd7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,184; copy number 2: 4,502; copy number 3: 14,532; copy number 4: 24,536; copy number 5: 8,136; copy number 6: 4,670; copy number 7: 4; copy number 8: 463; copy number 9: 884; copy number 11: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 888 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:187,668,912–187,746,028, 5 genes, copy number 9: SST, RTP2, AC072022.1, BCL6, AC072022.2.
- chr3:193,593,144–193,697,811, 3 genes, copy number 9: OPA1, OPA1-AS1, Y_RNA.
- chr20:26,103,416–64,327,972, 876 genes, copy number 9 (broad region; genes not listed).
- chr21:13,038,160–13,120,807, 4 genes, copy number 11: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
